Somatic mutation profile of tumor specimen TCGA-UF-A7JV-01A (aliquot TCGA-UF-A7JV-01A-11D-A34J-08) from TCGA case TCGA-UF-A7JV, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Hypopharynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 62.9 years (22,985 days).
Specimen TCGA-UF-A7JV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28ec215b-a720-43d6-97f8-f512c8fefbef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A7JV-10A (Blood Derived Normal), aliquot TCGA-UF-A7JV-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4379c207-fb6b-4756-b673-40dc66600b27

The open-access MAF lists 79 somatic variants for this specimen: 57 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 21, Nonsense Mutation 8, Splice Site 2, Intron 1, In Frame Del 1, Splice Region 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 21/90 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.2620A>T p.T874S | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV100252355; called by muse, mutect2, varscan2
- ADAM8 | c.1708G>A p.V570M | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.448); catalogued as COSV101291635; called by muse, mutect2, varscan2
- AMOTL1 | c.2392G>C p.A798P | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); catalogued as COSV100504258; called by muse, mutect2
- ANKS1B | c.2247G>C p.E749D | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100243970; called by muse, mutect2, varscan2
- ANO7 | c.951C>G p.F317L (on ENST00000274979; = p.F263L on NM_001370694.2) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99237848; called by muse, mutect2, varscan2
- ARHGAP17 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99253118; called by muse, mutect2, varscan2
- ASXL3 | c.5487G>C p.K1829N | Missense Mutation (SNP) | VAF 74/299 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV52473358; called by muse, mutect2, varscan2
- ATP6V1C1 | c.271C>A p.L91M | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV101214916; called by muse, mutect2, varscan2
- BAIAP2L1 | c.1517C>G p.S506W | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99133871; called by muse, mutect2, varscan2
- BEND7 | c.353C>G p.S118* | Nonsense Mutation (SNP) | VAF 28/116 reads (24%) | catalogued as rs754764345, COSV100346513; called by muse, mutect2, varscan2
- BRCA2 | c.10177G>C p.E3393Q | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.624); catalogued as COSV100583027; called by muse, mutect2, varscan2
- C4B | c.3871C>T p.R1291C | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs574457656; called by muse, mutect2
- C6 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99666801; called by muse, mutect2, varscan2
- CAP1 | c.1393A>C p.K465Q | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV100472100; called by muse, mutect2, varscan2
- CD163L1 | c.3844G>T p.V1282L | Missense Mutation (SNP) | VAF 26/117 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100549849; called by muse, mutect2, varscan2
- CD300LF | c.852C>A p.Y284* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100042680; called by muse, mutect2, varscan2
- DOT1L | c.2692-1G>C p.X898_splice | Splice Site (SNP) | VAF 9/50 reads (18%) | catalogued as COSV101288560, COSV101288626; called by muse, mutect2, varscan2
- DRC7 | c.1629G>C p.E543D | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100395455; called by muse, mutect2, varscan2
- DUS4L | c.117-1G>A p.X39_splice | Splice Site (SNP) | VAF 16/87 reads (18%) | catalogued as rs533668907, COSV99709088; called by muse, mutect2, varscan2
- EIF2A | c.1705C>T p.Q569* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99855833; called by muse, mutect2, varscan2
- ENTHD1 | c.1670G>A p.R557H | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs753644902, COSV57319440; called by muse, varscan2
- FAM53B | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as COSV100483986; called by muse, varscan2
- GNAI2 | c.162G>A p.K54= | Splice Region (SNP) | VAF 22/91 reads (24%) | catalogued as COSV99806885; called by muse, mutect2, varscan2
- GRAP2 | c.659A>T p.Q220L | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.035); catalogued as COSV100702920; called by mutect2, varscan2
- LAG3 | c.747C>G p.F249L | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.136); catalogued as COSV99179895; called by muse, mutect2, varscan2
- LAMA2 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 25/102 reads (25%) | catalogued as rs868019991, COSV70351944; called by muse, mutect2, varscan2
- MTDH | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV100292435; called by muse, mutect2, varscan2
- MTUS2 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as COSV101462133; called by muse, mutect2, varscan2
- NLRC3 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100072586; called by muse, mutect2, varscan2
- OR1D2 | c.408G>C p.M136I | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV100513888; called by muse, mutect2, varscan2
- OR1L8 | c.277A>G p.I93V | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as rs767054614, COSV100508475; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.845T>A p.F282Y (on ENST00000374531 / NM_001037293.2; = p.F314Y on NM_053016.6) | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100092835; called by muse, mutect2, varscan2
- PIK3CG | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 30/110 reads (27%) | catalogued as rs867282260, COSV100782716, COSV63249428; called by muse, mutect2, varscan2
- PLCL2 | c.3008C>T p.T1003I (on ENST00000615277 / NM_001144382.2; = p.T877I on NM_015184.5) | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV101196621; called by muse, mutect2, varscan2
- PLEK | c.340A>T p.T114S | Missense Mutation (SNP) | VAF 53/261 reads (20%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.985); catalogued as COSV99310813; called by muse, mutect2, varscan2
- PPFIA3 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1167529021, COSV100494795; called by muse, mutect2, varscan2
- PTGDS | c.498C>G p.F166L | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.937); catalogued as COSV56400124, COSV99811766; called by muse, mutect2, varscan2
- RAB34 | c.523C>T p.Q175* | Nonsense Mutation (SNP) | VAF 21/106 reads (20%) | catalogued as COSV99972599; called by muse, mutect2, varscan2
- RAG1 | c.2440G>C p.E814Q | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100200767; called by muse, mutect2, varscan2
- RFX3 | c.2075C>G p.A692G | Missense Mutation (SNP) | VAF 82/123 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV101137613; called by muse, mutect2, varscan2
- S100A10 | c.250A>T p.N84Y | Missense Mutation (SNP) | VAF 52/228 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV100916717; called by muse, mutect2, varscan2
- SAGE1 | c.2219C>G p.S740* | Nonsense Mutation (SNP) | VAF 69/325 reads (21%) | catalogued as COSV100186907; called by muse, mutect2, varscan2
- SS18 | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.449); catalogued as COSV52260494; called by muse, mutect2, varscan2
- TAS1R1 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs779636670, COSV100039555; called by muse, mutect2, varscan2
- TNFRSF6B | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV99422834; called by muse, varscan2
- TNS2 | c.755C>T p.S252F (on ENST00000314250 / NM_170754.4; = p.S262F on NM_015319.2) | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100047720; called by muse, mutect2, varscan2
- TRIOBP | c.2182G>T p.D728Y | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV100730751; called by muse, mutect2, varscan2
- TTN | c.29431G>A p.D9811N (on ENST00000591111; = p.D8884N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/370 reads (22%) | PolyPhen possibly damaging (0.691); catalogued as COSV60444025; called by muse, mutect2, varscan2
- ZBTB7B | c.103G>A p.D35N (on ENST00000292176; = p.D69N on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99420980; called by muse, mutect2, varscan2
- ZNF131 | c.1390G>A p.E464K (on ENST00000509156 / NM_001330707.2; = p.E430K on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV100185314; called by muse, mutect2, varscan2
- ZNF208 | c.817A>T p.T273S | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.127); catalogued as COSV101236938; called by muse, varscan2
- ZNF91 | c.2455A>G p.I819V | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.946); catalogued as rs915532712, COSV100322437; called by muse, mutect2, varscan2
- ITSN2 | c.3552_3554del p.T1185del | In Frame Del (DEL) | VAF 32/162 reads (20%) | called by pindel, varscan2
- LONP1 | c.2834_2835insTT p.A946Sfs*71 | Frame Shift Ins (INS) | VAF 27/170 reads (16%) | called by mutect2, pindel, varscan2
- TAF1C | c.2440del p.M814Cfs*83 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, pindel
- ANK3 | c.9642G>A p.K3214= | Silent (SNP) | VAF 28/189 reads (15%) | catalogued as COSV99779028; called by muse, mutect2, varscan2
- ARHGAP39 | c.363G>A p.E121= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV99430603; called by muse, mutect2, varscan2
- ATR | c.7572T>A p.G2524= | Silent (SNP) | VAF 34/136 reads (25%) | catalogued as COSV100637880; called by muse, mutect2, varscan2
- CCNB3 | c.1110G>A p.K370= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV99328723; called by muse, mutect2, varscan2
- COL20A1 | c.1617G>A p.L539= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV58916744; called by muse, varscan2
- DNAH2 | c.7698C>T p.F2566= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as rs148588175; called by muse, mutect2, varscan2
- EPHB4 | c.2076C>T p.L692= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV100639439; called by muse, mutect2, varscan2
- GOLPH3 | c.612C>T p.L204= | Silent (SNP) | VAF 52/236 reads (22%) | catalogued as COSV99417085; called by muse, mutect2, varscan2
- HEATR1 | c.1971C>A p.I657= | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV100857555; called by muse, mutect2, varscan2
- HRH3 | c.438G>A p.Q146= | Silent (SNP) | VAF 25/56 reads (45%) | catalogued as COSV100420489; called by muse, mutect2, varscan2
- LEPR | c.3090G>A p.E1030= | Silent (SNP) | VAF 63/216 reads (29%) | catalogued as rs372019263; called by muse, mutect2, varscan2
- LRRN4 | c.570C>T p.I190= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1330614425, COSV101125394; called by muse, mutect2, varscan2
- MRAP | c.84G>A p.E28= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as rs1179958411, COSV100353231; called by muse, mutect2, varscan2
- PPP1R10 | c.168G>A p.Q56= | Silent (SNP) | VAF 46/167 reads (28%) | catalogued as COSV100919781; called by muse, mutect2, varscan2
- PWWP3B | c.1830G>A p.V610= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV61799821; called by muse, mutect2, varscan2
- RANBP2 | c.5709G>A p.S1903= | Silent (SNP) | VAF 115/570 reads (20%) | catalogued as rs776484428, COSV51701825; called by muse, mutect2, varscan2
- SLITRK2 | c.2526C>T p.I842= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as rs1569507254, COSV59424247; called by muse, mutect2, varscan2
- SPEG | c.570C>T p.S190= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as rs762453666, COSV56664804; called by muse, mutect2, varscan2
- TTYH1 | c.231C>T p.P77= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as rs148537788; called by muse, varscan2
- U2AF2 | c.1072C>T p.L358= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs1473521588, COSV100454174; called by muse, mutect2, varscan2
- UGT2A1 | c.381T>C p.D127= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as COSV99684059; called by muse, mutect2, varscan2
- MACF1 | c.15832-10656G>A | Intron (SNP) | VAF 21/86 reads (24%) | catalogued as COSV99242638; called by muse, mutect2, varscan2
